Somatic mutation profile of tumor specimen TCGA-3B-A9HJ-01A (aliquot TCGA-3B-A9HJ-01A-11D-A387-09) from TCGA case TCGA-3B-A9HJ, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of pelvis; Age at diagnosis: 68.3 years (24,962 days).
Specimen TCGA-3B-A9HJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb8da54e-134c-4f49-befb-ffd2dfb4a5da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3B-A9HJ-10A (Blood Derived Normal), aliquot TCGA-3B-A9HJ-10A-01D-A38A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ccdec2ec-974b-4ae0-97e1-a7df52d1d23e

The open-access MAF lists 12 somatic variants for this specimen: 7 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 4, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRE1 | c.2290-1G>A p.X764_splice | Splice Site (SNP) | VAF 5/82 reads (6%) | catalogued as rs1157323351, COSV99165880; called by muse, mutect2
- GNE | c.518T>C p.I173T (on ENST00000396594 / NM_001128227.3; = p.I142T on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as CM102236, COSV100930149; called by muse, mutect2
- KCNH2 | c.1375G>A p.V459M | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV51222439; called by muse, mutect2
- LYZ | c.106G>A p.D36N | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.087); catalogued as COSV54260466, COSV99720213; called by muse, varscan2
- OR7D4 | c.758G>A p.G253E | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100432875; called by muse, mutect2, varscan2
- OR7D4 | c.266G>A p.S89N | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs1370532240, COSV100432876; called by muse, mutect2, varscan2
- KITLG | c.586G>A p.D196N | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.875); called by muse, mutect2
- BAG6 | c.1689C>T p.V563= (on ENST00000676571; = p.V516= on NM_080702.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/83 reads (12%) | catalogued as COSV99277639; called by muse, mutect2, varscan2
- FAT3 | c.12651C>T p.D4217= | Silent (SNP) | VAF 8/98 reads (8%) | catalogued as rs1268532489, COSV53123766; called by muse, mutect2
- RECK | c.609A>G p.Q203= | Silent (SNP) | VAF 6/69 reads (9%) | catalogued as rs374632258; called by muse, mutect2
- ZSWIM4 | c.936G>A p.Q312= | Silent (SNP) | VAF 16/104 reads (15%) | catalogued as COSV99585439; called by muse, mutect2, varscan2
- MIR510 | n.9C>A | RNA (SNP) | VAF 5/37 reads (14%) | called by muse, mutect2
